Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE0-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation:

Left partial hepatectomy

Segmentectomy (No. 5)

Cholecystectomy

Organ:

Liver, left lobe (14.0 x 11.5 x 5.5 cm, 289.0 gm)

Liver, segment 5 (9.5 x 5.5 x 3.8 cm, 90.0 gm)

Gallbladder (8.0 cm in length, 3.0 cm in diameter)

Lesion:

[A single mass in hepatectomy specimen]

Size: 6.5 x 5.0 x 7.5 cm

Cut surface: A well-demarcated, lobulated, yellowish tan, solid and firm mass

Gross type: Multinodular confluent

Extent: Confined to the hepatic parenchyme

Resection margin: Not involved, grossly (safety margin: 3.0 cm)

Remaining parenchyme: Unremarkable

[A small mass in segmentectomy specimen]

Size: 3.0 x 2.5 x 2.2 cm

Cut surface: An ill-defined, pale tan and firm mass with necrosis

Gross type: Multinodular confluent

Extent: Confined to the hepatic parenchyme

Resection margin: Not involved, grossly (safety margin: 0.6 cm)

Remaining parenchyme: Unremarkable

[Gallbladder]

Serosal surface: Yellowish green and smooth

Mucosal surface: Dark green and velvety

Wall: 0.2 cm in thickness

Representative sections are submitted.

Gross photo: Present

Blocks

GB, gallbladder x 1

T1-3, tumor mass and surrounding hepatic parenchyme in segment specimen x 3

T4-7 and TB, tumor mass and surrounding hepatic parenchyme in hapatectomy specimen x 5

NB and L, nontumorous liver parenchyme x 2

ICD-O-3

Carcinoma, hepatocellular NOS

Site: Liver C22.0

8170/3

JA 5/20/14

[page 2 of 2]
MICROSCOPIC:

Tumor type: Hepatocellular carcinoma,
Edmondson-steiner grade
The worst differentiation IV
The major differentiation III
Histologic type: Trabecular, tubular, solid
Cell type: Hepatic
Fatty change: No
Cholangiocarcinoma: No
Fibrous capsule formation: No
Capsular infiltration: No
Septum formation: No
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: No
Vascular invasion: No
Bile duct invasion: No
Remaining liver parenchyme:
Chronic hepatitis: Yes
Etiology: HBV
Grade, lobular: Mild
Grade, portoperiportal: Mild
Stage (fibrosis): Septal
Cirrhosis: No
Dysplastic nodule: No

NOT reported. Gross:

Liver, left, ectomy, hepatocellular caricnoma
Liver, ectomy, hepatocellular carcinoma
Gallbladder, ectomy, chronic cholecystitis

DIAGNOSIS:

Liver, left, partial hepatectomy:
Hepatocellular carcinoma

Liver, segment No.5, segmetectomy:
Hepatocellular carcinoma with marked necrosis

Galllbladder, cholecystectomy:
Chronic cholecystitis (autolysis)

Suggestion :

Source: NCI Genomic Data Commons file ea07f673-b9d3-49aa-bb25-be7addd21595 (TCGA-DD-AAE0.C8EB705D-E9F9-4101-9B7F-EE4968CA5781.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).